MMRF case MMRF_2187 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2b81d589-cadc-4f6c-8c23-e5311f758f01

Demographics
Sex at birth: male; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.5 years (19,528 days); ISS stage: III; Days to last known disease status: 1 day; Days to last follow up: 1 day.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 11 days.

Follow-up (2 entries)
- Days to follow up: -6 days; ECOG performance status: 3.
- Follow-up contact recording only the day: day 1.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Immunoglobulin M 0.25 g/L.
- Serum Free Immunoglobulin Light Chain, Kappa 7.66 mg/dL.
- Total Protein 9.8 g/dL.
- Creatinine 141 µmol/L.
- Immunoglobulin A 0.4 g/L.
- Blood Urea Nitrogen 9.64 mmol/L.
- M Protein 4.7 g/dL.
- Absolute Neutrophil 2.16 ×10⁹/L.
- Immunoglobulin G 72.5 g/L.
- Platelets 186 ×10⁹/L.
- Glucose 6.66 mmol/L.
- Calcium 2.38 mmol/L.
- Leukocytes 5.4 ×10⁹/L.
- Beta 2 Microglobulin 11 µg/mL.
- Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL.
- Hemoglobin 3.04 mmol/L.
- Albumin 21 g/L.

Other clinical attributes
- Day -6: Weight: 101 kg; Height: 187 cm.

Biospecimens (3 samples)
- Sample MMRF_2187_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2187_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
- Sample MMRF_2187_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
